Somatic mutation profile of tumor specimen TCGA-KV-A6GE-01A (aliquot TCGA-KV-A6GE-01A-11D-A31X-10) from TCGA case TCGA-KV-A6GE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 65.7 years (23,979 days).
Specimen TCGA-KV-A6GE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9307b9a7-530b-414c-a207-fa35ee6da9cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KV-A6GE-10A (Blood Derived Normal), aliquot TCGA-KV-A6GE-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37716002-be74-4d93-8868-93024d759fd6

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 26, Silent 7, Frame Shift Ins 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD14A-ACY1 | c.1618C>A p.R540S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53685764; called by muse, mutect2, varscan2
- AFG3L2 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV52313739; called by muse, mutect2, varscan2
- BAHD1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs762158993, COSV69083777; called by muse, mutect2, varscan2
- BLMH | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV55584890; called by muse, mutect2, varscan2
- CACNB1 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59998429; called by muse, mutect2, varscan2
- CREB3 | c.745T>C p.S249P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV59205996; called by muse, mutect2, varscan2
- EDEM1 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV56581392; called by muse, mutect2, varscan2
- ELMO3 | c.1406G>C p.R469P (on ENST00000652269; = p.R416P on NM_024712.5) | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV58526880; called by muse, mutect2, varscan2
- FILIP1 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52726231; called by muse, varscan2
- HMCN1 | c.6849T>G p.N2283K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54884107, COSV54888975; called by mutect2, varscan2
- KCNN2 | c.890A>G p.N297S (on ENST00000264773; = p.N509S on NM_021614.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53286432; called by muse, mutect2, varscan2
- MAP3K8 | c.1268T>G p.I423S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.142); catalogued as COSV53919246; called by muse, mutect2, varscan2
- MYH4 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs148833814; called by muse, mutect2, varscan2
- NRDE2 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV62962679; called by muse, mutect2, varscan2
- PACS1 | c.2448T>A p.Y816* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV57697143; called by muse, mutect2
- PARP4 | c.3187C>G p.P1063A | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV67961191; called by muse, varscan2
- PIK3C2B | c.2720T>C p.I907T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs780582509, COSV65810229; called by muse, mutect2, varscan2
- PLXND1 | c.4824T>C p.L1608= | Splice Region (SNP) | VAF 21/45 reads (47%) | catalogued as COSV60711121; called by muse, mutect2, varscan2
- PRMT5 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53545320; called by muse, mutect2, varscan2
- PRMT7 | c.1575+1G>A p.X525_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV59832774; called by muse, mutect2, varscan2
- SIPA1L2 | c.4877G>A p.G1626E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV53387453; called by muse, mutect2, varscan2
- SLC30A3 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV51984774; called by muse, varscan2
- TGS1 | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52699137; called by muse, varscan2
- TLR5 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV60558453; called by muse, mutect2, varscan2
- TNIK | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.119); catalogued as rs1418513695, COSV52678214; called by muse, varscan2
- TP53BP1 | c.1643C>T p.T548M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as rs758857922, COSV55498716; called by muse, mutect2, varscan2
- TRAPPC10 | c.1931G>A p.W644* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV52376437; called by muse, mutect2, varscan2
- TTN | c.81517A>T p.N27173Y (on ENST00000591111; = p.N19749Y on NM_003319.4) | Missense Mutation (SNP) | VAF 42/150 reads (28%) | PolyPhen benign (0.26); catalogued as COSV59966599; called by muse, mutect2, varscan2
- VPS13C | c.7546C>T p.R2516W (on ENST00000644861 / NM_020821.3; = p.R2473W on NM_017684.5) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs751759185, COSV51141062; called by muse, varscan2
- ZNF677 | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV61719832; called by muse, mutect2, varscan2
- DSCAML1 | c.1491dup p.T498Hfs*9 (on ENST00000321322; = p.T438Hfs*9 on NM_020693.4) | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- ENPP1 | c.2638del p.E880Nfs*3 | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | called by mutect2, pindel*, varscan2
- F13A1 | c.1109_1112dup p.W371Cfs*9 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- CD163L1 | c.2526A>T p.I842= | Silent (SNP) | VAF 64/126 reads (51%) | catalogued as COSV58013794; called by muse, mutect2, varscan2
- CLCF1 | c.57C>A p.L19= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56861473; called by mutect2, varscan2
- LILRA5 | c.609T>G p.P203= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV56642147; called by muse, mutect2, varscan2
- MDGA1 | c.807C>A p.P269= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV51793917, COSV51798746; called by muse, mutect2, varscan2
- MUC16 | c.2988A>G p.V996= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV67456166; called by muse, mutect2, varscan2
- NPTN | c.453C>T p.V151= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV54737216; called by muse, mutect2, varscan2
- USP45 | c.1563A>G p.R521= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV59679738; called by muse, mutect2, varscan2
